Surgical pathology report (de-identified scan), TCGA case TCGA-FG-A711, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-A711-01A (Primary Tumor).

[page 1 of 5]
Observation Date and Time

Entry Date

Component Results

Component

SPECIMEN DESCRIPTION

(NOTE)

Surgical Pathology Report

Patient Name: ---

Accession #: ---

Med. Rec #: ---

Submitting Physician: ---

*****Clinical History*****

Brain lesion

ADDENDA:

Addendum added: [REDACTED]

Addendum added: [REDACTED]

Addendum added: [REDACTED]

*****Final Pathologic Diagnosis*****

- A. Left frontal lobe, excision:
- Glial neoplasm, low grade. See comment.

Comment: The histological profile and Ki-67 labelling index are consistent with a low grade (WHO grade II) glial neoplasm. Though in many areas the cells assume an oligodendroglial profile, in other areas more pleomorphic elements with astrocytic appearance are present. More sections as well as assays for 1p/19q deletions are pending and an addendum will be issued subsequently.

The immunohistochemical and/or in situ hybridization tests reported here, except for those addressing HER-2Neu overexpression, have been developed and their performance characteristics determined by the

Oligodendroglioma, grade II
945013 NOS
core
Site Brain, supratentorial
C710
path
Brain, frontal lobe
C711
JW 8/22/13

UUID:SE5F767F-755E-4361-AA92-42D09DE41386

[page 2 of 5]
[REDACTED]

laboratories in the
at the --- and are not required to
have nor do they have FDA approval.

[REDACTED]

*****Addendum Report*****

Addendum

Status: Signed Out

Detection of 1p36 and 19q by 1p36 1q25 and 19q13/19p13
Dual-Color Probe Sets

Telephone: ---, FAX: ---
Case No --- Outside Case#:
Pathologist --- Patient Name:
Source of case --- Patient MRN:
Block used A2
Tissue fixation formalin-fixed tissue
Tissue source Brain

RESULTS

Ratio of 0.67 Cell count of 1p/1q: 118
Ratio of 0.48 Cell count of 19q/19p: 120
Interpretation of Results: A) 1p loss; B) 19q loss

Interpretation of findings:

A) (positive) The majority of tumors cells displayed 2 control chromosome 1q25 signals and 1 chromosome 1p36 signals (locus of interest). The ratio of 1p36/1q25 is <0.8. The results are consistent with the loss of 1p36 locus of interest. B) (positive) The majority of tumors cells displayed 2 control chromosome 19p13 signals and 1 chromosome 19q13 signals (locus of interest). The ratio of 19q13/19p13 is <0.8. The results are consistent with the loss of 1p36 locus of interest.

Number of Observers: 2
Test Interpreted By: ---

Comments

The resultant FISH section/slide is scanned by a trained licensed medical technologist and analyzed using a FDA-approved, validated semi-automated scanning imaging workstation and accompanying imaging

[page 3 of 5]
[REDACTED]

analysis software . The resultant FISH section/slide is then presented to the interpreting Pathologist, who will reviews the FISH results from and compares them to the results manually observed under Fluorescence Microscope. Therefore the ratio is enumerated by computer-aided counting as well as manual counting.

Interpretation of Test

The ratio for probe set 1 is derived by dividing the total number of 1p36 signals by the total number of 1q25 signals in at least 20 interphase nuclei with

nonoverlapping nuclei in the neoplastic glial cells. Cells with no signals or with signals of only one color are disregarded. The ratio for probe set 2 is derived by dividing the total number of 19q13 signals by the total number of 19p13 signals in at least 2 sets of 20 interphase nuclei with nonoverlapping nuclei in the neoplastic glial cells at two different areas of the sample. Cells with no signals or with signals of only one color are disregarded. References ranges for our laboratory for allelic loss versus no allelic loss were established by evaluating both probe sets in a series of 40 normal cases from 10 different organs. For both probe set 1 and 2 a ratio of less than 0.80 taken from at least 2 sets of 20 interphase nuclei at 2 different areas with nonoverlapping nuclei is consistent with allelic loss.

Limitations

ANALYTE SPECIFIC REAGENT: The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristics determined by the

. They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

[REDACTED]

Addendum

Status: Signed Out

A: Left frontal lobe, excision.

- Oligodendroglioma (WHO grade II).

In-situ assays detect loss of both 1p and 19q loci.

[REDACTED]

[page 4 of 5]
[REDACTED]

Addendum

Status: Signed Out

Unchanged.

The KI-67 stain was performed by manual immunohistochemistry method.

[REDACTED]

*****INTRAOPERATIVE CONSULTATION DIAGNOSIS:*****

AF1. Left frontal tumor: (FROZEN SECTION PERFORMED)
- Infiltrating glial neoplasm.

Examining pathologist:---

*****MICROSCOPIC:*****

Sections show an infiltrating mild to moderately cellular neoplasm composed of glial elements having round to ovoid nuclei and scant cytoplasm. In areas, nuclear pleomorphism with more elongated form is identified. Focally, clusters of minigemistocytes are present. Mitotic figures are occasional. Immunostain for GFAP is positive in occasional cells and a Ki-67 stain shows a proliferation index in the range of 1-2%.

*****SPECIMEN(S) RECEIVED:*****

Neuropathology Brain, Reg

*****GROSS DESCRIPTION:*****

The specimen is received in one properly labeled container of which is originally received in frozen section, with the patient's name and accession number.

A. The specimen is designated "left frontal tumor" and consists of a 7.9 x 6.0 x 3.1 cm portion of tan-gray brain tissue. Upon serially sectioning a 5.8 x 5.7 x 3.4 cm tan-white homogeneous mass is identified. A representative section is submitted for frozen section and is resubmitted as received in cassette AF1. [REDACTED]

[page 5 of 5]
Summary of Cassettes: AF1, frozen section tissue; A1-6, random sections of mass

Lab Use Only: _____
Lab Use Only: _____

Gross description by: ---

HPA Discrepancy		///

Source: NCI Genomic Data Commons file c6f9a016-b414-4172-a755-cda265f91acf (TCGA-FG-A711.5E5F767F-755E-4361-AA92-42D09DE41386.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).